Gene-level copy-number profile of tumor specimen ALCH-B4EQ-TTP1-A from ALCHEMIST case ALCH-B4EQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.4 years (28,287 days).
Specimen ALCH-B4EQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fc2b85f1-1bb5-475f-b27e-7269cdde04fe.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4EQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/7fdfab89-9b26-403e-86e0-4266fc5311ab

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 127; copy number 1: 3,614; copy number 2: 36,076; copy number 3: 13,225; copy number 4: 3,690; copy number 5: 1,611; copy number 6: 6; copy number 7: 27; copy number 8: 17.

Homozygous deletions (total copy number 0; autosomes only): 127 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,339,624–36,385,924, 1 gene: STK40.
- chr4:1,715,952–1,721,358, 1 gene: TMEM129.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr6:130,366,017–132,169,374, 28 genes: TMEM200A, Y_RNA, AL583803.1, SMLR1, EPB41L2, AKAP7, AL137222.1, RPL21P67, ARG1, MED23, ENPP3, RNU4-18P, OR2A4, CTAGE9, AC005587.1, MIR548H5, ENPP1, SELENOKP2, RN7SKP245, AL139805.1, AL117378.1, AL117378.2, CCN2, AL133346.1, AL021408.1, MIR548AJ1, AL021408.2, LINC01013.
- chr8:28,890,395–29,854,543, 19 genes (within-gene range 0–1): HMBOX1, Metazoa_SRP, HMBOX1-IT1, RNA5SP260, AC108449.2, KIF13B, AC108449.3, AC108449.1, HMGB1P23, DUSP4, AC084262.2, AC084262.1, AC084026.2, AC084026.1, AC084026.3, RPL17P33, LINC00589, LINC02099, AC131254.1.
- chr11:12,094,008–12,359,144, 3 genes (within-gene range 0–2): MICAL2, MIR6124, AC079329.1.
- chr11:46,376,402–46,386,608, 3 genes (within-gene range 0–2): MIR4688, MDK, CHRM4.
- chr15:25,172,635–25,250,940, 43 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:41,825,099–41,972,557, 11 genes (within-gene range 0–1): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310, AC020659.1, EHD4, AC039056.2, EHD4-AS1.
- chr15:70,503,907–70,505,928, 1 gene: LINC02205.
- chr15:92,805,770–92,949,230, 4 genes (within-gene range 0–2): AC106028.2, AC106028.4, CHASERR, AC013394.1.
- chr15:92,904,399–92,904,475, 1 gene (within-gene range 0–2): MIR3175.
- chr17:40,092,793–40,115,442, 2 genes (within-gene range 0–2): NR1D1, AC068669.1.
- chr18:48,826,051–48,952,052, 2 genes (within-gene range 0–2): AC093567.1, SMAD7.
- chr20:3,732,685–3,823,882, 7 genes (within-gene range 0–1): HSPA12B, C20orf27, SPEF1, CENPB, CDC25B, LINC01730, AL109804.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,661 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,724,637–6,730,012, 1 gene, copy number 5: LINC01672.
- chr4:59,551,142–59,834,167, 4 genes, copy number 5–7: AC096588.1, AC093857.1, Y_RNA, RNU6-1325P.
- chr4:67,612,652–67,701,155, 1 gene, copy number 7 (within-gene range 2–7): UBA6.
- chr4:67,701,209–68,497,604, 25 genes, copy number 5–7: UBA6-AS1, ST3GAL1P1, AC079880.1, AC079880.2, GNRHR, SNORA62, TMPRSS11CP, TMPRSS11D, TMPRSS11A, TMPRSS11GP, RNU6-95P, GCOM2, MTND2P41, TMPRSS11F, SYT14P1, FTLP10, TMPRSS11BNL, TMPRSS11B, AC098799.3, AC098799.1, AC098799.2, APOOP4, YTHDC1, MT2P1, TMPRSS11E.
- chr4:68,614,419–74,794,523, 131 genes, copy number 5–7 (broad region; genes not listed).
- chr4:76,114,659–76,234,536, 3 genes, copy number 5 (within-gene range 2–5): NUP54, AC110795.1, SCARB2.
- chr6:15,102,946–15,245,000, 3 genes, copy number 6: AL050335.1, RN7SL332P, AL136162.1.
- chr7:51,016,212–57,837,046, 168 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr7:105,530,209–105,567,677, 2 genes, copy number 5 (within-gene range 3–5): AC073073.1, RINT1.
- chr8:46,549,089–49,907,446, 66 genes, copy number 5 (broad region; genes not listed).
- chr8:65,526,738–99,877,580, 527 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:102,252,273–102,412,759, 1 gene, copy number 5 (within-gene range 4–5): UBR5.
- chr8:102,417,979–143,713,898, 529 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:67,265,842–67,319,953, 2 genes, copy number 5: GGTA2P, CAND1.
- chr12:67,443,105–67,670,919, 4 genes, copy number 5: LINC02408, LINC02442, DYRK2, AC078777.1.
- chr12:68,487,687–71,441,898, 61 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr14:30,874,514–35,122,517, 72 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr14:37,171,888–42,989,483, 56 genes, copy number 5 (within-gene range 4–5): SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1, AL357094.1, KRT8P1, LINC00639, AL132994.1, AL132994.2, Y_RNA, SEC23A, AL109628.1, SEC23A-AS1, PPIAP4, GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2, GLRX5P3, COILP1, FBXO33, AL049828.1, LINC02315, AL391516.1, AL356596.1, AL121821.3, AL121821.2, AL121821.1, LRFN5, FKBP1BP1, AL445074.1, AL442163.1, AL450442.1, AL442163.2, AL442163.3, YWHAQP1, AL163153.1.
- chr14:71,848,606–71,928,596, 1 gene, copy number 5: AC005993.1.
- chr14:92,794,305–92,839,947, 1 gene, copy number 5: GOLGA5.
- chr20:45,745,737–45,791,932, 3 genes, copy number 6 (within-gene range 2–6): HNRNPA1P3, WFDC3, SPINT5P.

Autosomal genes at a single copy (total copy number 1): 3,610. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
